Somatic mutation profile of tumor specimen TCGA-BP-4977-01A (aliquot TCGA-BP-4977-01A-01D-1462-08) from TCGA case TCGA-BP-4977, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.4 years (20,950 days).
Specimen TCGA-BP-4977-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9908feda-a30b-46e8-9cf7-fda48ea8f2f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4977-11A (Solid Tissue Normal), aliquot TCGA-BP-4977-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/158ce85f-d6d9-4e79-b232-abd18ba5240c

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Frame Shift Del 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53574993; called by muse, mutect2, varscan2
- AKR1B10 | c.489C>G p.S163R | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV62055416; called by muse, mutect2, varscan2
- ATP7B | c.3840G>A p.M1280I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54438183; called by muse, mutect2, varscan2
- BIRC6 | c.5618T>G p.I1873S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV70198995; called by muse, varscan2
- CABCOCO1 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV57592907; called by muse, mutect2, varscan2
- CAPN9 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55233342; called by muse, mutect2, varscan2
- COBL | c.319A>T p.I107F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV54344981; called by muse, mutect2, varscan2
- COL5A2 | c.3566A>G p.N1189S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV66409543; called by muse, mutect2, varscan2
- CUBN | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64715136; called by muse, mutect2, varscan2
- FBN2 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV52511308; called by muse, mutect2, varscan2
- FXYD5 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV61568637; called by muse, mutect2, varscan2
- HIKESHI | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV53574159; called by muse, mutect2, varscan2
- LACC1 | c.887C>A p.A296E | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1158812110, COSV57829074; called by muse, mutect2, varscan2
- LHX6 | c.935C>T p.A312V (on ENST00000373755 / NM_001242334.2; = p.A341V on NM_014368.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV61344636; called by muse, mutect2, varscan2
- MBD4 | c.1264T>C p.Y422H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV51444582; called by muse, mutect2, varscan2
- MOB2 | c.455T>A p.L152Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57318498; called by muse, mutect2
- MON2 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54806889; called by muse, mutect2, varscan2
- OR3A1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs749032687, COSV60163021; called by muse, varscan2
- P2RX6 | c.1062C>G p.F354L | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60383821, COSV60385079; called by muse, mutect2
- PARP11 | c.43T>A p.L15I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV57394911; called by muse, mutect2, varscan2
- PLEKHG7 | c.328T>G p.S110A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV67337827; called by muse, mutect2, varscan2
- PNRC2 | c.277T>A p.Y93N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100355677; called by muse, mutect2, varscan2
- RANBP2 | c.5980G>C p.G1994R | Missense Mutation (SNP) | VAF 142/378 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV51700749; called by muse, mutect2, varscan2
- SEC63 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64599505; called by muse, mutect2, varscan2
- SLC22A4 | c.1270T>A p.F424I | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52358071; called by muse, mutect2, varscan2
- SSH2 | c.662A>C p.N221T | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV52171922; called by muse, mutect2, varscan2
- TAS1R2 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV64744861; called by muse, mutect2, varscan2
- THBS1 | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as rs367660638; called by muse, mutect2, varscan2
- TMEM165 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63529184; called by muse, mutect2, varscan2
- TNC | c.2657A>T p.K886I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV60784588; called by muse, mutect2, varscan2
- ZBTB41 | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.193); catalogued as COSV66359124; called by muse, mutect2, varscan2
- ZNF782 | c.988A>G p.R330G | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56652442; called by muse, mutect2, varscan2
- GALNT5 | c.834del p.P279Lfs*10 | Frame Shift Del (DEL) | VAF 33/74 reads (45%) | called by mutect2, pindel, varscan2
- VHL | c.607_608del p.Q203Gfs*52 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by pindel, varscan2
- WIPF1 | c.652_675del p.T218_N225del | In Frame Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- ATE1 | c.1464G>A p.Q488= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV56436201; called by muse, mutect2, varscan2
- CDH1 | c.2224C>T p.L742= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV55732362; called by muse, mutect2, varscan2
- ITPRID1 | c.2376C>A p.I792= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs1435355870, COSV60074193; called by muse, mutect2, varscan2
- RNF32 | c.447C>T p.H149= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV58732255; called by muse, mutect2, varscan2
- SERPINE2 | c.177G>A p.A59= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs780761280, COSV51455815; called by muse, mutect2, varscan2
- SLC7A3 | c.627C>T p.F209= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV53227386; called by muse, varscan2
- TEX11 | c.2031G>T p.L677= (on ENST00000344304; = p.L662= on NM_031276.3) | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as COSV60230211; called by muse, mutect2, varscan2
- SPHK2 | c.872+59T>C | Intron (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99709590; called by muse, mutect2, varscan2
